Gene-level copy-number profile of tumor specimen TCGA-AZ-6607-01A from TCGA case TCGA-AZ-6607, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 69.7 years (25,448 days).
Specimen TCGA-AZ-6607-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.f1766538-f258-498f-ba5d-f567aaef86b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AZ-6607-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8fb19b24-9723-4d65-b698-395100187430

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 80; copy number 2: 1,190; copy number 3: 14,513; copy number 4: 9,282; copy number 5: 11,648; copy number 6: 14,408; copy number 7: 1,732; copy number 8: 4,419; copy number 9: 11; copy number 10: 2,357; copy number 11: 53; copy number 12: 82; copy number 19: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AZ-6607-01A-11D-1834-01): tumor purity 0.52, ploidy 3.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:107,834,586–108,138,610, 5 genes: LINC00636, LINC00635, AC012020.1, CD47, LINC01215.
- chr3:125,225,669–125,595,497, 8 genes: ZNF148, DUTP1, DNAJB6P7, RNU6-232P, SNX4, Y_RNA, Y_RNA, OSBPL11.
- chr6:161,347,417–162,727,775, 1 gene (within-gene range 0–3): PRKN.
- chr6:162,568,379–163,315,492, 5 genes (within-gene range 0–3): KRT8P44, PACRG, AL590286.1, AL590286.2, PACRG-AS2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 8,672 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:46,993,723–47,838,106, 11 genes, copy number 9 (within-gene range 6–9): GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1.
- chr7:70,972–159,233,377, 3,012 genes, copy number 8–10 (broad region; genes not listed).
- chr8:37,843,268–43,674,591, 153 genes, copy number 11–19 (within-gene range 4–19) (broad region; genes not listed).
- chr12:66,767–74,728,851, 1,840 genes, copy number 8 (broad region; genes not listed).
- chr12:97,150,081–119,959,754, 466 genes, copy number 8 (broad region; genes not listed).
- chr17:41,323,427–51,336,240, 527 genes, copy number 7 (broad region; genes not listed).
- chr17:74,256,896–83,095,122, 414 genes, copy number 7 (broad region; genes not listed).
- chr18:47,390–49,837,623, 789 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr18:49,814,133–49,814,443, 2 genes, copy number 7: SCARNA17, AC090227.1.
- chr20:87,250–64,313,132, 1,458 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 46. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
